Gene-level copy-number profile of tumor specimen BLGSP-71-08-00042-01B from CGCI case BLGSP-71-08-00042, project CGCI-BLGSP (Burkitt Lymphoma Genome Sequencing Project). Sex at birth: male; Vital status: Alive; Primary diagnosis: Burkitt lymphoma, NOS (Includes all variants); Tissue or organ of origin: Hematopoietic system, NOS.
Specimen BLGSP-71-08-00042-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file ee94d3de-f68c-436b-a894-9010e167fd84.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator BLGSP-71-08-00042-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,780 have no estimate.
https://portal.gdc.cancer.gov/files/9b22f7da-5d49-4252-9403-ae15b8627548

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 13; copy number 1: 4,049; copy number 2: 51,229; copy number 3: 3,244; copy number 4: 207; copy number 5: 20; copy number 6: 19; copy number 7: 7; copy number 8: 2; copy number 9: 28; copy number 10: 1; copy number 11: 1; copy number 13: 3; copy number 14: 2; copy number 26: 8; copy number 49: 1; copy number 53: 3; copy number 58: 2; copy number 80: 4.

Homozygous deletions (total copy number 0; autosomes only): 13 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:88,915,081–88,915,378, 1 gene (within-gene range 0–1): IGKV7-3.
- chr2:88,947,301–88,979,081, 3 genes (within-gene range 0–1): IGKV1-5, IGKV1-6, IGKV3-7.
- chr2:89,009,982–89,040,745, 4 genes (within-gene range 0–1): IGKV1-9, IGKV2-10, IGKV3-11, IGKV1-12.
- chr22:22,893,692–22,905,025, 5 genes (within-gene range 0–1): IGLJ1, IGLC1, IGLJ2, IGLC2, IGLJ3.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 101 genes in 33 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:5,925,550–5,970,683, 1 gene, copy number 6 (within-gene range 2–6): RSPH10B.
- chr7:57,828,331–57,837,046, 2 genes, copy number 9: AC023141.7, AC023141.13.
- chr7:74,082,933–74,122,525, 1 gene, copy number 5: LIMK1.
- chr7:74,964,705–75,031,528, 1 gene, copy number 9 (within-gene range 3–9): CASTOR2.
- chr7:102,479,976–102,517,777, 1 gene, copy number 5 (within-gene range 1–5): RASA4B.
- chr7:102,637,049–102,671,641, 3 genes, copy number 7 (within-gene range 3–7): AC105052.3, SPDYE2B, POLR2J2.
- chr8:12,205,759–12,206,389, 1 gene, copy number 5: ENPP7P12.
- chr8:12,310,962–12,318,316, 1 gene, copy number 49: DEFB130A.
- chr9:34,084,332–34,096,225, 1 gene, copy number 5 (within-gene range 3–5): AL354989.1.
- chr9:64,369,394–64,413,142, 1 gene, copy number 5 (within-gene range 4–5): ANKRD20A4P.
- chr9:64,462,819–64,466,498, 2 genes, copy number 6: CR769776.2, CYP4F25P.
- chr14:18,333,726–18,596,310, 6 genes, copy number 6 (within-gene range 4–13): CR383658.1, RNU6-458P, CR383658.2, BNIP3P6, CR383656.10, CR383656.7.
- chr14:18,588,274–18,602,129, 2 genes, copy number 6: CR383656.9, OR11H12.
- chr14:18,630,318–18,637,421, 3 genes, copy number 9: LINC02297, CR383656.1, CR383656.12.
- chr15:21,293,653–21,295,201, 1 gene, copy number 6: AC068446.1.
- chr15:21,927,657–22,095,472, 9 genes, copy number 7–9 (within-gene range 7–16): NF1P2, MIR5701-3, OR11J6P, AC134980.1, OR11H3P, OR11K1P, OR4Q1P, OR4H6P, OR4N4.
- chr15:22,178,107–22,185,402, 2 genes, copy number 8: IGHV1OR15-3, IGHV4OR15-8.
- chr16:21,401,089–21,515,131, 3 genes, copy number 5: AC008740.2, NPIPB3, AC005632.6.
- chr16:28,802,743–28,817,828, 2 genes, copy number 6: AC145285.2, AC145285.1.
- chr16:32,250,620–32,255,922, 2 genes, copy number 14: AC133485.3, TP53TG3D.
- chr16:32,356,981–32,380,049, 2 genes, copy number 58: AC133548.1, ACTR3BP3.
- chr16:32,600,299–32,615,639, 1 gene, copy number 5: AC137800.1.
- chr16:32,635,673–32,636,045, 1 gene, copy number 5: AC133569.1.
- chr16:32,715,931–32,788,944, 8 genes, copy number 26: AC138907.6, ABHD17AP7, AC138907.2, AC138907.4, HERC2P5, AC138907.8, AC138907.9, AC138907.10.
- chr16:32,847,713–32,888,874, 4 genes, copy number 11–13: IGHV2OR16-5, BCAP31P2, SLC6A10P, AC142086.1.
- chr16:33,094,204–33,570,935, 20 genes, copy number 9–80 (within-gene range 4–80): HERC2P8, AC145350.4, AC145350.1, ABHD17AP9, AC138869.1, AC138869.2, TP53TG3C, AC138869.3, AC141257.2, TP53TG3E, AC141257.3, TP53TG3B, AC141257.1, AC141257.4, TP53TG3F, AC136944.5, AC136944.1, AC136944.2, AC136944.4, AC136944.3.
- chr17:46,372,855–46,579,691, 6 genes, copy number 5–7 (within-gene range 5–10): NSFP1, RDM1P2, LRRC37A2, ARL17A, RN7SL199P, FAM215B.
- chr21:13,654,073–13,654,356, 1 gene, copy number 6: AL050303.2.
- chr21:13,762,338–13,777,266, 3 genes, copy number 53: FEM1AP1, AL050303.1, TERF1P1.
- chr22:18,361,820–18,404,206, 3 genes, copy number 5: FAM230J, AC011718.1, PPP1R26P3.
- chr22:18,486,999–18,491,247, 1 gene, copy number 5 (within-gene range 4–5): AC023490.2.
- chr22:18,527,157–18,530,573, 2 genes, copy number 5–10: AC023490.3, TMEM191B.
- chr22:21,473,000–21,551,461, 4 genes, copy number 5 (within-gene range 3–5): PI4KAP2, AP000557.1, RN7SKP221, RIMBP3C.

Autosomal genes at a single copy (total copy number 1): 1,198. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
